Gene-level copy-number profile of tumor specimen TCGA-29-1692-01B from TCGA case TCGA-29-1692, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 58.0 years (21,193 days).
Specimen TCGA-29-1692-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.a8a0d815-8d32-4735-a550-cac3a9bfc703.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-29-1692-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2 (2 files); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/484dd9bd-b5c0-40ba-8a8d-d693d823aa8e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 6,969; copy number 2: 18,433; copy number 3: 22,104; copy number 4: 7,471; copy number 5: 2,527; copy number 6: 2,054; copy number 7: 171; copy number 8: 84.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-29-1692-01): tumor purity 0.53, ploidy 2.84, whole-genome doublings 1 (call status: snp_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 255 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:141,324,213–144,445,844, 59 genes, copy number 8 (within-gene range 5–8): ZBTB38, AC010184.1, KRT18P35, RASA2, RASA2-IT1, YWHAQP6, LINC02618, TPT1P3, AC112771.1, RNF7, AC112504.2, GRK7, AC112504.3, HMGN2P25, ATP1B3, RNU6-509P, ATP1B3-AS1, AC112504.1, TFDP2, AC133435.1, RNU6-425P, GK5, XRN1, RNU6-1294P, RNU1-100P, ATR, AC109992.1, AC109992.2, RPL6P9, RNA5SP143, PLS1, PLS1-AS1, RN7SKP25, AC072028.1, TRPC1, RNU7-47P, PCOLCE2, AC021074.1, AC021074.3, PAQR9, AC021074.2, PAQR9-AS1, U2SURP, AC026304.1, AC018450.2, CHST2, AC018450.1, PBX2P1, SLC9A9, AC131210.1, SLC9A9-AS1, SLC9A9-AS2, GAPDHP47, ST13P15, AC073358.1, AC107421.1, DIPK2A, RNA5SP144, AC011592.1.
- chr3:168,249,522–168,830,599, 1 gene, copy number 8 (within-gene range 6–8): EGFEM1P.
- chr3:168,551,854–169,869,935, 24 genes, copy number 8: MIR551B, RPSAP33, RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997, MECOM, MECOM-AS1, RPL22P1, AC007849.1, SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31.
- chr3:170,996,347–179,394,936, 98 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr11:74,490,519–74,669,117, 3 genes, copy number 7 (within-gene range 4–7): LIPT2, AP001372.2, POLD3.
- chr11:123,939,543–125,139,587, 70 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,548. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
